Surgical pathology report (de-identified scan), TCGA case TCGA-56-7822, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-56-7822-01A (Primary Tumor).

[page 1 of 5]
Surg Path Final Report

* Final Report *

Result Type:
Result Date:
Result Status:
Result Title:
Verified By:
Encounter info:

Final Diagnosis (Verified)

Right upper lobe mass, wedge resection with frozen section and cytologic touch preparations:
Moderate to poorly differentiated squamous cell carcinoma.
Maximal tumor diameter is 1.2 cm.

Right upper lobe of lung, resection with frozen section:
Residual moderate to poorly differentiated squamous cell carcinoma.
Maximal tumor diameter is 6.4 cm.
Focus suspicious for lymphovascular invasion is seen.
Visceral pleural involvement is not identified.
Negative bronchial and vascular resection margins.
Three (3) benign peribronchial lymph nodes with no evidence of metastatic neoplasm.

Level 9 pulmonary ligament lymph node, excision:
One (1) benign lymph node with no evidence of metastatic neoplasm.

Level 8 paraesophageal (below carina) lymph nodes, excision:
Three (3) benign lymph nodes with no evidence of metastatic neoplasm.
One (1) lymph node demonstrates focally calcified basophilic material.
Special stains for acid-fast and fungal organisms are negative.

4R lower paratracheal (right) lymph nodes, excision:
Two (2) benign lymph nodes with no evidence of metastatic neoplasm.

Level 10 hilar lymph node, excision:
One (1) large lymph node demonstrating metastatic squamous cell carcinoma

Printed by:
Printed on:

Page 1 of 3
(Continued)

[page 2 of 5]
Surg Path Final Report

* Final Report *

(micrometastasis seen in lymph node subcapsular sinus).

2R upper paratracheal (right) lymph node, excision:

One (1) benign lymph node with no evidence of metastatic neoplasm.

Level 7 subcarinal lymph nodes, excision:

Three (3) benign lymph nodes with no evidence of metastatic neoplasm.

Comment: A total of 14 lymph nodes were sampled, one (1) of which (the level 10 hilar lymph node) shows a micrometastatic focus of squamous cell carcinoma. AJCC pathologic stage: T2b,N1.

Signature Line

Gross Description (Verified)

"FSA." All frozen section tissue is submitted in cassette "FSA."

"A, NSFA." The specimen consists of a 1.2 x 0.5 x 0.3 cm gray-tan, firm tissue fragment. A portion of the specimen has been submitted at frozen section. The remaining specimen is submitted. Free in the container are multiple soft, gray-tan tissue fragments measuring less than a millimeter. "A," fragments, all, tea bag.

"FSB." All frozen section tissue is submitted in cassette "FSB."

"B, NFSB." The specimen consists of a 15.0 x 11.0 x 4.0 cm right lung. There is a 4.5 x 4.0 cm firm, puckered area on the pleural surface. There is also a 0.4 x 0.4 cm gray-white, firm area on the pleura. The remaining pleural surface is blue-gray. The specimen has previously been sectioned by the pathologist to reveal a 5.1 x 3.5 x 6.4 cm gray-tan mass with cavitation. The pleural surface overlying the mass is inked black. This mass grossly appears to abut the overlying pleural surface and comes to within 3.0 cm of the bronchial margin. The remaining lung parenchyma is red-tan and markedly congested. On examination, one intraparenchymal lymph node is identified. This measures 0.5 cm. Three peribronchial lymph nodes are identified. These range in size from 0.3 to 2.0 cm. "B1," vascular margin; "B2-B5," mass to include

Printed by:
Printed on:

Page 2 of 3
(Continued)

[page 3 of 5]
Surg Path Final Report

* Final Report *

overlying pleura; "B6," gray-white, firm area on pleura and intraparenchymal lymph node; "B7," peribronchial lymph nodes, representative.

"C, 9 pulmonary ligament." The specimen consists of a 1.3 cm gray-black lymph node. All lymphoid tissue is submitted into cassette "C."

"D, 8 paraesophageal (below carina)." The specimen consists of 3 gray-black to yellow-black lymph nodes ranging in size from 1.2 x 0.7 x 0.7 cm to 1.8 x 1.3 x 0.5 cm. The second largest lymph node is markedly calcified. "D1," smallest lymph node; "D2," largest lymph node; "D3," markedly calcified lymph node, all; light decal "D3."

"E, 4R lower paratracheal (right)." The specimen consists of 2 gray-tan lymph nodes measuring 1.9 x 1.0 x 0.4 cm and 2.5 x 1.7 x 0.6 cm. All lymphoid tissue is submitted into cassettes "E1-E2." "E1," smallest lymph node; "E2," largest lymph node.

"F, 10 hilar." The specimen consists of a 4.2 x 2.1 x 1.7 cm gray-black, irregular lymph node. "F1-F4," fragments, all.

"G, 2R upper paratracheal (right)." The specimen consists of a 1.0 x 0.9 x 0.5 cm yellow-tan, fatty tissue fragment. On examination, a 0.7 cm gray-tan lymph node is identified. All lymphoid tissue is submitted into cassette "G," representative.

"H, 7 subcarinal." The specimen consists of 3 gray-tan to gray-black lymph node fragments ranging in size from 0.9 x 0.4 x 0.5 cm to 2.2 x 2.0 x 1.0 cm. All lymphoid tissue is submitted into cassette "H1-H3."

"I, Expo project." Received in formalin is one yellow cassette with the following label:

Signature Line

Clinical Information (Verified)

HTN, carpal tunnel syndrome.

Frozen Section Diagnosis (Verified)

- A) Right lung, upper lobe, wedge biopsy of lesion [REDACTED]
Gross: 1.2 cm greatest dimension fragment of hard gray tissue. Also present are a few small (1 mm or less) fragments of softer gray tissue. One half of the large fragment submitted for FS. Squash preps made from small fragments.
Diagnosis: Squamous cell carcinoma. [REDACTED]
- B) Right lung, upper lobe, lobectomy [REDACTED]
Gross: 15 x 11 x 4 RUL with large palpable tumor and palpable pleura. Bronchial margin sampled as FSB. Section through tumor shows gray cut surface with cavitations. Tumor sampled for [REDACTED] tumor study.
FS Diagnosis: Bronchial margin negative for tumor. [REDACTED]

Completed Action List:

Printed by:
Printed on:

Page 3 of 3
(End of Report)

[page 4 of 5]
Preliminary Report

Result Type:
Result Date:
Result Status:
Result Title:
Verified By:
Encounter info:

Preliminary Discussion (Verified)

Right upper lobe mass, wedge resection with frozen section and cytologic touch preparations:

Moderate to poorly differentiated squamous cell carcinoma.

Maximal tumor diameter is 1.2 cm.

Right upper lobe of lung, resection with frozen section:

Residual moderate to poorly differentiated squamous cell carcinoma.

Maximal tumor diameter is 6.4 cm.

Focus suspicious for lymphovascular invasion is seen.

Visceral pleural involvement is not identified.

Negative bronchial and vascular resection margins.

Three (3) benign peribronchial lymph nodes with no evidence of metastatic neoplasm

Level 9 pulmonary ligament lymph node, excision:

One (1) benign lymph node with no evidence of metastatic neoplasm.

Level 8 paraesophageal (below carina) lymph nodes, excision:

Three (3) benign lymph nodes with no evidence of metastatic neoplasm.

One (1) lymph node demonstrates focally calcified basophilic material.

See comment.

4R lower paratracheal (right) lymph nodes, excision:

Two (2) benign lymph nodes with no evidence of metastatic neoplasm.

Level 10 hilar lymph node, excision:

One (1) large lymph node demonstrating foci suspicious for micrometastasis (see comment).

2R upper paratracheal (right) lymph node, excision:

One (1) benign lymph node with no evidence of metastatic neoplasm.

Printed by:
Printed on:

Page 1 of 2
(Continued)

[page 5 of 5]
Level 7 subcarinal lymph nodes, excision:
Three (3) benign lymph nodes with no evidence of metastatic neoplasm.

Comment: Final report pending review of recut sections on the suspected metastasis in the hilar lymph nodes (specimen F) and special stains for microorganisms on the basophilic deposits within the paraesophageal lymph node.

Signature Line

Completed Action List:

Printed by:
Printed on:

Source: NCI Genomic Data Commons file 6f1e6470-e891-42c1-90da-a2fbe0501baf (TCGA-56-7822.53197469-7424-4F46-B67C-B16364E8DF79.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).